Somatic mutation profile of tumor specimen CPT008922 (aliquot CPT008922-0002) from CPTAC case 21BR002, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008922: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b59d431-68d0-47a6-be4f-b27e39c2ecfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008551 (Blood Derived Normal), aliquot CPT008551-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6aa11b08-ff42-46c8-be5a-d92c596a0c29

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 8, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 2, Intron 1, Splice Region 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 112/288 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ASPM | c.4157C>T p.A1386V | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs376642620; called by muse, mutect2, varscan2
- EBLN2 | c.282A>T p.Q94H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.934); catalogued as rs768254818, COSV55596816; called by muse, mutect2, varscan2
- IGBP1P2 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1206719613; called by muse, mutect2, varscan2
- IST1 | c.976C>G p.P326A (on ENST00000535424 / NM_001270976.1; = p.F311L on NM_014761.4) | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100324490; called by muse, mutect2, varscan2
- KANSL1 | c.3299G>A p.R1100H (on ENST00000574590 / NM_001193465.2; = p.R1101H on NM_015443.4) | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1289935394; called by muse, mutect2, varscan2
- KCTD10 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 16/307 reads (5%) | catalogued as COSV57327337; called by muse, mutect2
- KIF21B | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 130/389 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100145263; called by mutect2, varscan2
- LINGO2 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 68/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471771066, COSV58056542; called by muse, mutect2, varscan2
- MYO7A | c.285C>T p.Y95= | Splice Region (SNP) | VAF 40/132 reads (30%) | catalogued as rs1555054892; called by muse, mutect2, varscan2
- OR6F1 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 158/354 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs755047673, COSV57466695; called by muse, varscan2
- PLCXD3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as rs751201584, COSV60614634; called by muse, mutect2, varscan2
- SEC16A | c.3110T>G p.L1037R | Missense Mutation (SNP) | VAF 110/540 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV51520885; called by muse, varscan2
- SSH1 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 94/424 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as rs370013672, COSV58455247; called by muse, mutect2, varscan2
- TNFSF9 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1370796364; called by muse, mutect2
- TRAV8-4 | c.232G>C p.G78R | Missense Mutation (SNP) | VAF 65/416 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200152714; called by muse, mutect2, varscan2
- USP48 | c.1245G>A p.M415I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57608314, COSV57614578; called by muse, mutect2, varscan2
- WDR7 | c.2748G>C p.K916N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV54359210; called by muse, mutect2, varscan2
- FAM228B | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GREB1 | c.2231C>G p.T744R | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KIT | c.2925T>A p.D975E | Missense Mutation (SNP) | VAF 99/477 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- KRTAP5-7 | c.439A>G p.N147D | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by mutect2, varscan2
- MIS18BP1 | c.2176dup p.I726Nfs*5 | Frame Shift Ins (INS) | VAF 42/181 reads (23%) | called by mutect2, pindel, varscan2
- OR4X1 | c.264del p.V89Sfs*25 | Frame Shift Del (DEL) | VAF 97/508 reads (19%) | called by mutect2, pindel, varscan2
- PDE3A | c.1199C>A p.S400* | Nonsense Mutation (SNP) | VAF 70/304 reads (23%) | called by muse, mutect2, varscan2
- PKD2 | c.2896G>T p.V966F | Missense Mutation (SNP) | VAF 60/399 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TF | c.1379G>A p.W460* | Nonsense Mutation (SNP) | VAF 89/355 reads (25%) | called by muse, mutect2, varscan2
- UBAP2 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 65/343 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ZNF638 | c.629del p.D210Vfs*48 | Frame Shift Del (DEL) | VAF 56/265 reads (21%) | called by mutect2, pindel, varscan2
- DOLK | c.300G>A p.Q100= | Silent (SNP) | VAF 81/424 reads (19%) | called by muse, mutect2, varscan2
- FAM222B | c.339C>T p.L113= | Silent (SNP) | VAF 156/608 reads (26%) | catalogued as rs771090558; called by mutect2, varscan2
- FLVCR1 | c.1497C>T p.V499= | Silent (SNP) | VAF 22/197 reads (11%) | called by muse, mutect2, varscan2
- PCDHA6 | c.2247G>A p.S749= | Silent (SNP) | VAF 41/194 reads (21%) | catalogued as COSV65343943; called by muse, mutect2, varscan2
- PLXNB1 | c.2094C>T p.P698= | Silent (SNP) | VAF 90/202 reads (45%) | catalogued as rs1490043187; called by muse, mutect2, varscan2
- RDX | c.33A>C p.T11= | Silent (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- TKFC | c.228C>T p.I76= | Silent (SNP) | VAF 61/284 reads (21%) | catalogued as rs144455681; called by muse, mutect2, varscan2
- TSHB | c.93C>T p.I31= | Silent (SNP) | VAF 64/408 reads (16%) | catalogued as rs369535357; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC009779.3 | c.*2856dup | 3'UTR (INS) | VAF 134/482 reads (28%) | called by mutect2, varscan2
- PSMC2 | c.71-1081T>C | Intron (SNP) | VAF 13/106 reads (12%) | catalogued as rs769805683; called by muse, mutect2, varscan2
- SLC25A13 | c.-95G>A | 5'UTR (SNP) | VAF 4/36 reads (11%) | catalogued as rs1003114256, COSV55711324; called by muse, mutect2
- TPT1 | c.-33T>G | 5'UTR (SNP) | VAF 44/173 reads (25%) | called by muse, varscan2
